Surgical pathology report (de-identified scan), TCGA case TCGA-YG-AA3P, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Puerto Rico, specimen TCGA-YG-AA3P-06A (Metastatic).

ICD O-3

Melanoma NOS 87203
Site Back NOS C49.6
9/25/30/14

Surgical Pathology and Cytopathology

Name	Age
Lab No.	Rec.Number
Phys	Ins. Plan
Date of Birth	Room No.
Date of Procedure	Date Received
Date Report	

Tissue Examination Report:

Specimen : Upper-Back Mass

SPECIMEN consists of a roundish fragment of yellowish adipose tissue measuring 5 x 4.5 cm. Externally it presents a yellowish color. On section a roundish, tumoral mass is identified measuring 2.6 cm being close to the inked margin of the specimen. The lesion presents a reddish brown color and a coarsely, granular appearance, being rubbery to firm in consistency. The remaining is mostly yellowish adipose tissue. Margins inked. (5 cassettes)

DIAGNOSIS:

UPPER-BACK MASS EXCISION:

- FIBROADIPOSE TISSUE.
- METASTATIC MELANOMA.
- NECROSIS PRESENT.
- THE TUMOR IS AT 1 MM FROM THE INKED MARGIN.

Pathologist

This report is confidential and contains privileged information. Inappropriate disclosure by accident you receive this report please contact us immediately.

Criteria	hw 1/8/14	Yes	No

Source: NCI Genomic Data Commons file 4d34a872-13fb-4686-a21b-f7898570bd15 (TCGA-YG-AA3P.9FE4AE17-704F-4480-9329-45B5D532C253.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).